Somatic mutation profile of tumor specimen HCM-CSHL-0248-C19-01A (aliquot HCM-CSHL-0248-C19-01A-11D-A78T-36) from HCMI case HCM-CSHL-0248-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 53.4 years (19,501 days).
Specimen HCM-CSHL-0248-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffc15728-c122-4aff-8e97-76d627c39071.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0248-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0248-C19-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11cd209f-4bb0-4557-a412-0b490850007a

The open-access MAF lists 149 somatic variants for this specimen: 110 protein-altering or splice-affecting, 28 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 28, Nonsense Mutation 11, Intron 4, Splice Region 4, 5'UTR 3, 3'UTR 3, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 52/178 reads (29%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 96/351 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 139/403 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99285771; called by muse, mutect2, varscan2
- ADGRE4P | n.2430C>T | Splice Region (SNP) | VAF 15/175 reads (9%) | catalogued as rs939596340; called by muse, mutect2
- AIFM1 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 42/512 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs763317252, COSV54857468; called by muse, mutect2
- ANOS1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 72/512 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52916948, COSV52917470; called by muse, mutect2, varscan2
- CACNA2D1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 37/429 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs769700955, COSV100665162, COSV62375610; called by muse, mutect2
- CD248 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as rs751114440, COSV60936700; called by muse, mutect2, varscan2
- CES3 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs780705221, COSV100310009; called by muse, mutect2, varscan2
- CHST12 | c.102C>G p.F34L | Missense Mutation (SNP) | VAF 38/567 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV51676255; called by muse, mutect2
- COL6A3 | c.3271G>A p.V1091I | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.406); catalogued as rs373915980; ClinVar: uncertain significance; called by muse, mutect2
- CRAT | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs767437298; called by muse, mutect2, varscan2
- DMXL1 | c.7996G>T p.E2666* | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | catalogued as COSV60710872; called by muse, mutect2, varscan2
- EHF | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57669623; called by muse, mutect2
- ELFN1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs780207326, COSV70033975; called by muse, mutect2, varscan2
- FAM135A | c.3827C>G p.P1276R (on ENST00000370479 / NM_001351599.1; = p.P1063R on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99526547; called by muse, mutect2
- FAM9A | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.736); catalogued as rs1309504625; called by muse, mutect2, varscan2
- FAXDC2 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100394092; called by muse, mutect2, varscan2
- FBXW7 | c.1787C>T p.S596F (on ENST00000281708 / NM_001349798.2; = p.S516F on NM_018315.5) | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55905007, COSV55968840, COSV55969630; called by muse, mutect2, varscan2
- FBXW7 | c.664C>T p.R222* (on ENST00000281708 / NM_001349798.2; = p.R142* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 24/330 reads (7%) | catalogued as rs920052554, COSV55897378; called by muse, mutect2
- FCAMR | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV61367607; called by muse, mutect2, varscan2
- FGF6 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746672335, COSV57403329; called by muse, mutect2, varscan2
- FLRT1 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1356069352; called by muse, mutect2
- GPR50 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 58/447 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs374566932, COSV54443231; called by muse, mutect2, varscan2
- GPR84 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs765986834; called by muse, mutect2, varscan2
- KCNQ4 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs770763842; called by muse, mutect2, varscan2
- LRRN1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs147499906; called by muse, mutect2, varscan2
- LTBP4 | c.3286G>T p.E1096* (on ENST00000308370 / NM_001042544.1; = p.E1059* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 16/128 reads (13%) | catalogued as COSV52575215; called by muse, mutect2, varscan2
- MAGEC1 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs1307594003; called by muse, mutect2, varscan2
- MAPK12 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 48/390 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs770945104; called by mutect2, varscan2
- NAV1 | c.3652C>T p.R1218* | Nonsense Mutation (SNP) | VAF 41/125 reads (33%) | catalogued as COSV55214307; called by muse, mutect2, varscan2
- NCAPD3 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs534584578, COSV73258180; called by muse, mutect2, varscan2
- NSUN5 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782131563; called by muse, mutect2, varscan2
- OR10G3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV57809647; called by muse, mutect2, varscan2
- OR5L2 | c.674T>A p.I225N | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65723810; called by muse, mutect2
- PCDH11X | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 119/591 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV53487981; called by muse, mutect2, varscan2
- PLIN4 | c.1922C>T p.T641M (on ENST00000301286; = p.T656M on NM_001367868.2) | Missense Mutation (SNP) | VAF 79/591 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs200977488; called by muse, mutect2, varscan2
- PLP2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 62/690 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs782572477; called by muse, mutect2
- POLL | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 106/436 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV54577401; called by muse, mutect2, varscan2
- PPP1R9B | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 60/463 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1374299692; called by muse, mutect2, varscan2
- PTCHD1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771692412; called by muse, mutect2, varscan2
- RBP3 | c.2278G>T p.V760L | Missense Mutation (SNP) | VAF 111/445 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs782109249; called by muse, mutect2, varscan2
- RMND5B | c.285+8C>T | Splice Region (SNP) | VAF 44/295 reads (15%) | catalogued as rs770068571, COSV57743783; called by muse, mutect2, varscan2
- RYR2 | c.12541G>A p.G4181R | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs775477470, COSV63669927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A1 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 149/608 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780549162; called by muse, mutect2, varscan2
- SSRP1 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs748483435, COSV53479039; called by muse, mutect2, varscan2
- STARD9 | c.6781G>A p.V2261I | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867845466; called by muse, mutect2, varscan2
- STXBP3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64182510; called by muse, mutect2, varscan2
- TOX | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 49/395 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812616; called by muse, mutect2, varscan2
- TTBK1 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as rs1383120100; called by muse, mutect2, varscan2
- TTN | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 43/394 reads (11%) | PolyPhen benign (0.01); catalogued as rs199590524, COSV99045813; called by muse, mutect2, varscan2
- WDR91 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761361253; called by muse, mutect2, varscan2
- WNK4 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 164/539 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs201947637, COSV99889410; called by muse, mutect2, varscan2
- ADGRG6 | c.770G>A p.W257* | Nonsense Mutation (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- APOL5 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 59/509 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BMX | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA2D1 | c.2764-5T>C | Splice Region (SNP) | VAF 36/426 reads (8%) | called by muse, mutect2
- CALCRL | c.1372A>T p.N458Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); called by mutect2, varscan2
- CBY3 | c.120G>C p.Q40H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.398); called by muse, mutect2
- CD6 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, varscan2
- CDH23 | c.5915C>T p.S1972F | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CDH4 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 26/300 reads (9%) | called by muse, mutect2
- CEP43 | c.704T>C p.L235S | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHM | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- COL7A1 | c.8820T>G p.G2940= | Splice Region (SNP) | VAF 142/549 reads (26%) | called by muse, mutect2, varscan2
- CRACD | c.2608A>G p.K870E | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYNC2H1 | c.7355A>C p.K2452T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FGD5 | c.2916C>G p.S972R | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FRAS1 | c.3397G>A p.G1133S | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HARBI1 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HOXC9 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HTATSF1 | c.1039T>C p.W347R | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTR5A | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 272/641 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KDM6A | c.1847C>G p.T616S | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIAA1755 | c.1596C>A p.S532R | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAN1A1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAP3K21 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- METTL14 | c.1298A>T p.N433I | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MPDZ | c.1860A>C p.K620N | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NECAB3 | c.644-1G>A p.X215_splice | Splice Site (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- NOP58 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NR3C2 | c.1823A>T p.D608V | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN3 | c.1433C>A p.T478K (on ENST00000335750 / NM_001330195.2; = p.T105K on NM_004796.6) | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NSRP1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NT5C3A | c.314T>G p.I105S (on ENST00000610140 / NM_001374335.1; = p.I71S on NM_016489.13) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB5 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4D | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 83/456 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZD4 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.006); called by muse, mutect2
- PGLYRP4 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 90/422 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- PIP4K2B | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- PKHD1 | c.6284C>A p.T2095N | Missense Mutation (SNP) | VAF 52/453 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PLGRKT | c.12A>G p.I4M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PROM2 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRN2 | c.559C>G p.R187G | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- RO60 | c.1224A>T p.K408N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- RYR2 | c.6763T>A p.L2255I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SEMA3A | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 26/367 reads (7%) | called by muse, mutect2
- SHROOM2 | c.3166C>T p.L1056F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS3 | c.1320T>A p.S440R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TEP1 | c.3625G>A p.G1209S | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- TSC2 | c.1080_1091del p.L361_I364del | In Frame Del (DEL) | VAF 79/410 reads (19%) | called by mutect2, pindel, varscan2
- TTN | c.24661T>A p.S8221T (on ENST00000591111; = p.S7294T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | PolyPhen benign (0.039); called by mutect2, varscan2
- TXNRD3 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.344); called by muse, mutect2
- WDR48 | c.1958A>G p.D653G | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 82/356 reads (23%) | called by mutect2, pindel, varscan2
- ZNF267 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- ZNF273 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- ZNF343 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF84 | c.2158_2161del p.F720Hfs*15 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- ACD | c.1254C>T p.H418= (on ENST00000620338; = p.H329= on NM_022914.3) | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as rs560864093; called by muse, mutect2, varscan2
- CASKIN1 | c.4272C>T p.D1424= | Silent (SNP) | VAF 49/355 reads (14%) | called by muse, mutect2, varscan2
- CCDC80 | c.2712G>A p.A904= | Silent (SNP) | VAF 101/415 reads (24%) | catalogued as COSV99245019; called by muse, mutect2, varscan2
- CDH2 | c.1839C>T p.C613= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs754880999, COSV52275510; called by muse, mutect2, varscan2
- CDKAL1 | c.111G>A p.K37= | Silent (SNP) | VAF 17/200 reads (9%) | called by muse, mutect2
- CLEC4M | c.1029C>T p.D343= | Silent (SNP) | VAF 23/217 reads (11%) | catalogued as rs370711365; called by muse, mutect2, varscan2
- DCAF12L1 | c.816C>A p.G272= | Silent (SNP) | VAF 75/221 reads (34%) | called by muse, mutect2, varscan2
- ECEL1 | c.87C>T p.R29= | Silent (SNP) | VAF 41/259 reads (16%) | called by muse, mutect2, varscan2
- FOSL2 | c.798G>A p.V266= | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2, varscan2
- MAB21L2 | c.456C>T p.I152= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as COSV58261353; called by muse, mutect2, varscan2
- MGAM | c.5319C>T p.A1773= | Silent (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2
- MYH13 | c.2892C>G p.T964= | Silent (SNP) | VAF 50/170 reads (29%) | called by muse, varscan2
- NOC2L | c.423G>A p.K141= | Silent (SNP) | VAF 41/324 reads (13%) | called by muse, mutect2, varscan2
- NRK | c.4413C>A p.G1471= | Silent (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
- NSG2 | c.144A>C p.T48= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- P2RX1 | c.453C>A p.A151= | Silent (SNP) | VAF 55/499 reads (11%) | catalogued as COSV56653370; called by muse, mutect2, varscan2
- PUM3 | c.1764G>A p.K588= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as rs1363434044, COSV65896562; called by muse, mutect2, varscan2
- RBPJL | c.1191C>T p.G397= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as rs1336661307; called by muse, mutect2
- REXO1 | c.1731C>T p.S577= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as COSV50074875; called by muse, mutect2, varscan2
- SPINDOC | c.1125G>A p.P375= | Silent (SNP) | VAF 46/398 reads (12%) | catalogued as rs764895479, COSV53693969; called by muse, mutect2, varscan2
- SPOCK2 | c.696C>T p.A232= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as rs370648887; called by muse, mutect2, varscan2
- STT3A | c.1032C>T p.P344= | Silent (SNP) | VAF 13/221 reads (6%) | called by muse, mutect2
- TMEM132C | c.2460C>T p.H820= | Silent (SNP) | VAF 63/186 reads (34%) | catalogued as rs561705907, COSV59414400; called by muse, mutect2, varscan2
- TMPRSS15 | c.2844T>C p.Y948= | Silent (SNP) | VAF 17/239 reads (7%) | called by muse, mutect2
- TNFRSF11A | c.1026G>A p.Q342= | Silent (SNP) | VAF 126/483 reads (26%) | called by muse, mutect2, varscan2
- TTC17 | c.945G>T p.V315= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as COSV50013380; called by muse, mutect2, varscan2
- ZNF783 | c.66G>A p.S22= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as rs766377882; called by muse, mutect2, varscan2
- ZNF835 | c.372G>A p.A124= | Silent (SNP) | VAF 110/461 reads (24%) | catalogued as COSV101606327; called by muse, mutect2, varscan2
- ACOT12 | c.-5T>A | 5'UTR (SNP) | VAF 42/262 reads (16%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1388T>G | Intron (SNP) | VAF 25/139 reads (18%) | catalogued as COSV100341901; called by muse, mutect2, varscan2
- CCN6 | c.*51_*52insC | 3'UTR (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- COL11A1 | c.-12C>A | 5'UTR (SNP) | VAF 93/332 reads (28%) | catalogued as COSV100617542; called by muse, mutect2, varscan2
- PDHB | c.96+72C>T | Intron (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- PHOX2B | c.*49G>C | 3'UTR (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- PZP | c.428-22T>C | Intron (SNP) | VAF 41/180 reads (23%) | called by muse, mutect2, varscan2
- SF3B1 | c.416-345G>C | Intron (SNP) | VAF 23/210 reads (11%) | called by muse, mutect2, varscan2
- TMEM135 | c.*1909A>G | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- XIST | n.10946T>G | RNA (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- YTHDC1 | c.-30G>A | 5'UTR (SNP) | VAF 42/286 reads (15%) | catalogued as rs1226926525; called by muse, mutect2, varscan2
